Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4K2, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4K2-01A (Primary Tumor).

DOB:

Sex: F

Physician:

Accession:

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) LEFT THYROID LOBECTOMY AND ISTHMUS:
PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Left lobe

Multi-focal: No

Size = 1.8 cm

Extrathyroidal extension: Absent

Lymphovascular invasion: Absent

Resection Margins: Negative

Lymph nodes:

No tumor present in 1 lymph node

ICD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, nos C73.9

fw

10/4/12

GROSS DESCRIPTION

(A) LEFT THYROID LOBECTOMY AND ISTHMUS FOR FS - A hemithyroidectomy specimen with attached isthmus, the thyroid lobe (6.0 x 2.0 x 1.5 cm), and isthmus and adjacent soft tissue (1.0 x 1.0 x 0.5 cm). The thyroid capsule appear unremarkable. A well delineated brown-tan, soft confined lesion (1.8 x 1.5 x 1.5 cm) with a central well demarcated white-tan circumscribed focus (0.5 x 0.5 x 0.5 cm) is within the thyroid lobe. The remaining of thyroid tissue has brown-red, vaguely nodular surface.

A section from the tumor and normal thyroid is submitted for tumor bank.

SECTION CODE: A1, representative brown thyroid nodule including the white-tan focus for frozen; A2-A4, entire brown thyroid nodule submitted (A3, contains a slide from the brown thyroid nodule with a white-tan demarcated focus); A5, unremarkable thyroid; A6, sections from the isthmus and adjacent soft tissue.

*FS/DX: FOLLICULAR ADENOMA WITH TINY PAPILLARY MICROCARCINOMA (LIKELY INCIDENTAL).

CLINICAL HISTORY

Thyroid mass.

SNOMED CODES

T-B6000, M-80503, T-C4200, M-00110, "Some tests reported here may have been developed and performance characteristics determined by these tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report
File under: Pathology

Page 1 of 1

Source: NCI Genomic Data Commons file fe8ad061-fb4c-467c-a894-d9f5216ce9cb (TCGA-EL-A4K2.F7DCEAA1-8E7C-44CA-8537-3F2706AE1068.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).